Gene-level copy-number profile of tumor specimen ALCH-ABE5-TTP1-A from ALCHEMIST case ALCH-ABE5, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 44.9 years (16,386 days).
Specimen ALCH-ABE5-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 75892408-095b-4e28-9ec2-e7c2d3e1a1a2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ABE5-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/362981ce-9e48-4971-a241-a85ba960bba8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 6,391; copy number 2: 51,037; copy number 3: 294; copy number 4: 654.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:39,659,121–39,672,038, 1 gene: NT5C1A.
- chr2:86,815,339–86,861,924, 1 gene (within-gene range 0–2): CD8B.
- chr5:174,751,734–174,751,787, 1 gene (within-gene range 0–2): MIR4634.
- chr7:73,667,831–73,683,453, 2 genes (within-gene range 0–2): VPS37D, DNAJC30.
- chr12:109,553,715–109,573,580, 2 genes (within-gene range 0–2): MMAB, RNU4-32P.
- chr13:35,697,487–35,699,938, 1 gene: LINC00445.
- chr16:33,802,764–33,810,767, 2 genes: IGHV3OR16-12, AC136428.3.
- chr16:33,857,935–33,859,352, 2 genes: AC140658.2, IGHV3OR16-11.
- chr18:37,234,119–37,762,131, 7 genes (within-gene range 0–1): AC015961.1, CELF4, AC015961.2, AC090386.1, AC090386.2, AC129908.1, AC009899.1.
- chr22:41,938,737–41,947,152, 1 gene: CENPM.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 6,391. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
